CCDI case PBCGPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/6a4ffeca-a3ae-4bcd-aadc-e928e0fea80f

Demographics
Sex at birth: female; Race: white.

Biospecimens (3 samples)
- Sample 0DS6KM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS6L2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS6LG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
